Somatic mutation profile of tumor specimen TCGA-MM-A563-01A (aliquot TCGA-MM-A563-01A-11D-A25V-10) from TCGA case TCGA-MM-A563, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Tumor grade: G2; Age at diagnosis: 41.2 years (15,037 days).
Specimen TCGA-MM-A563-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b1b7554-e6f2-402a-8b58-40a1ccd65b41.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MM-A563-10A (Blood Derived Normal), aliquot TCGA-MM-A563-10A-01D-A25V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dc70b537-1e5f-4515-9f83-65d272b9cb3f

The open-access MAF lists 45 somatic variants for this specimen: 39 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Frame Shift Del 4, Silent 4, Nonsense Mutation 3, Splice Site 2, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTRT1 | c.230G>T p.G77V | Missense Mutation (SNP) | VAF 63/116 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100947549; called by muse, mutect2, varscan2
- AHNAK2 | c.14679G>A p.M4893I | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV60923736; called by muse, mutect2, varscan2
- ATAD2 | c.3492G>C p.R1164S | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.045); catalogued as COSV99784400; called by muse, mutect2, varscan2
- CARNS1 | c.2227G>T p.V743L | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100321869; called by muse, mutect2, varscan2
- CIITA | c.2670C>G p.S890R | Missense Mutation (SNP) | VAF 60/202 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.655); catalogued as COSV100161713, COSV60862169; called by muse, mutect2, varscan2
- DUSP2 | c.643G>C p.G215R | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99997044; called by muse, mutect2, varscan2
- EDIL3 | c.614G>T p.W205L | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56908704; called by muse, mutect2, varscan2
- FAM20B | c.19G>A p.V7I | Missense Mutation (SNP) | VAF 49/167 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs1327728264, COSV99762254; called by muse, mutect2, varscan2
- ITPR2 | c.3747T>G p.N1249K | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101189927; called by muse, mutect2, varscan2
- KCNK1 | c.334A>C p.S112R | Missense Mutation (SNP) | VAF 55/218 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100785873; called by muse, mutect2, varscan2
- KIF26B | c.2354A>C p.Y785S | Missense Mutation (SNP) | VAF 53/172 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100832044; called by muse, mutect2, varscan2
- KYNU | c.634G>A p.G212R | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV99933045; called by muse, mutect2, varscan2
- NUP188 | c.3014C>G p.T1005S | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.152); catalogued as COSV101001287; called by muse, mutect2
- NUP98 | c.4039T>A p.C1347S (on ENST00000359171 / NM_001365126.1; = p.C1330S on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100262011, COSV61431633; called by muse, mutect2
- NUP98 | c.4037C>G p.A1346G (on ENST00000359171 / NM_001365126.1; = p.A1329G on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100262013; called by muse, mutect2
- OR8B8 | c.140C>T p.T47I | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.005); catalogued as COSV100044966; called by muse, mutect2, varscan2
- PALB2 | c.1653T>G p.Y551* | Nonsense Mutation (SNP) | VAF 32/109 reads (29%) | catalogued as CM070241, COSV99848303; called by muse, mutect2, varscan2
- PDE4DIP | c.6792C>G p.I2264M | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.049); catalogued as COSV100518302; called by muse, mutect2, varscan2
- PRKAG1 | c.673G>A p.V225I | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.059); catalogued as COSV100305038; called by muse, mutect2, varscan2
- PRPF8 | c.954C>G p.Y318* | Nonsense Mutation (SNP) | VAF 79/265 reads (30%) | catalogued as COSV100517352; called by muse, mutect2, varscan2
- PSG8 | c.323T>G p.L108R | Missense Mutation (SNP) | VAF 72/307 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100126094; called by muse, varscan2
- RAB28 | c.512A>G p.Q171R | Missense Mutation (SNP) | VAF 77/213 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0.039); catalogued as COSV99986154; called by muse, mutect2, varscan2
- RBMS2 | c.169A>T p.N57Y | Missense Mutation (SNP) | VAF 145/499 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100008461; called by muse, mutect2, varscan2
- RNF43 | c.310A>G p.I104V | Missense Mutation (SNP) | VAF 67/172 reads (39%) | SIFT tolerated (0.59); PolyPhen benign (0.19); catalogued as COSV101348371; called by muse, mutect2, varscan2
- SGO2 | c.3648G>C p.Q1216H | Missense Mutation (SNP) | VAF 59/196 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100764646; called by muse, varscan2
- SMCHD1 | c.3254C>A p.S1085* | Nonsense Mutation (SNP) | VAF 14/50 reads (28%) | catalogued as COSV99861270; called by muse, mutect2, varscan2
- SOX13 | c.528G>A p.M176I | Missense Mutation (SNP) | VAF 152/550 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as COSV99689914; called by muse, varscan2
- SRRM2 | c.6689G>A p.S2230N | Missense Mutation (SNP) | VAF 62/189 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); catalogued as COSV99241369; called by muse, mutect2, varscan2
- STXBP5L | c.272C>A p.T91K | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as COSV99873253; called by muse, varscan2
- TNRC6B | c.4412C>G p.S1471C (on ENST00000454349 / NM_001162501.2; = p.S1361C on NM_015088.3) | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100109411; called by muse, mutect2, varscan2
- ULK1 | c.1096+1G>T p.X366_splice | Splice Site (SNP) | VAF 52/186 reads (28%) | catalogued as COSV100416712; called by muse, mutect2, varscan2
- VPS45 | c.581T>G p.V194G | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.355); catalogued as COSV100964883; called by muse, mutect2, varscan2
- ZNF486 | c.373G>C p.G125R | Missense Mutation (SNP) | VAF 71/215 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.655); catalogued as COSV100631185; called by muse, mutect2, varscan2
- ZRANB3 | c.394T>G p.Y132D | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99923233; called by muse, mutect2, varscan2
- AFF1 | c.753del p.V253Sfs*58 | Frame Shift Del (DEL) | VAF 38/123 reads (31%) | called by mutect2, pindel, varscan2
- CPT1B | c.47del p.P16Qfs*13 | Frame Shift Del (DEL) | VAF 26/83 reads (31%) | called by mutect2, pindel, varscan2
- DGKH | c.2025_2035+4del p.X675_splice | Splice Site (DEL) | VAF 8/33 reads (24%) | called by mutect2, pindel
- DUOXA2 | c.468_469del p.L157Gfs*8 | Frame Shift Del (DEL) | VAF 41/151 reads (27%) | called by mutect2, pindel, varscan2
- OCA2 | c.1421del p.F474Sfs*25 | Frame Shift Del (DEL) | VAF 42/191 reads (22%) | called by mutect2, pindel, varscan2
- DOCK11 | c.5301C>A p.A1767= | Silent (SNP) | VAF 68/124 reads (55%) | catalogued as COSV99353489; called by muse, mutect2, varscan2
- FNDC1 | c.975G>T p.L325= | Silent (SNP) | VAF 45/116 reads (39%) | catalogued as COSV51932079, COSV99795438; called by muse, mutect2, varscan2
- GPS2 | c.612T>C p.Y204= | Silent (SNP) | VAF 65/207 reads (31%) | catalogued as COSV100222857; called by muse, varscan2
- RNF169 | c.684A>G p.K228= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV100213300; called by muse, mutect2, varscan2
- INSYN2A | c.*1C>A | 3'UTR (SNP) | VAF 25/91 reads (27%) | catalogued as COSV99728546; called by muse, mutect2, varscan2
- PPFIA4 | c.1633-14G>T | Intron (SNP) | VAF 28/107 reads (26%) | catalogued as COSV99690465; called by muse, mutect2, varscan2
